Surgical pathology report (de-identified scan), TCGA case TCGA-EK-A2PG, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Gynecologic Oncology Group, specimen TCGA-EK-A2PG-01A (Primary Tumor).

[page 1 of 3]
ICD-0-3
Carcinoma, squamous cell 8070/3
Site: cervix, NOS 653.9
8/23/11

SURGICAL PATHOLOGY REPORT

Patient:
MRN:
Acct No:
Location:
SSN:

SURG. NO:
Collect Date:
Received Date:
Admitting Physician:
Ordering Physician:

Age/Sex: . /F

TISSUES:
A. ENDOCERVICAL BIOPSY

CLINICAL HISTORY:
Post-menopausal bleeding

FINAL DIAGNOSIS:
BIOPSIES, MASS, PROTRUDING INTO VAGINA:
POORLY DIFFERENTIATED AND NECROTIC SQUAMOUS CELL CARCINOMA.

GROSS DESCRIPTION:
Specimen is identified as endocervical biopsy and consists of scant tan hemorrhagic material measuring approximately 1/4 cc in volume. Totally submitted.

MICROSCOPIC DESCRIPTION:
Microscopic examination is performed.

Electronically signed by:

[page 2 of 3]
printed: /

Page 1
Chart Document

Female DOB:

Year Old

Home:

Office:

MRN:

- Pathology Report: Surgical Procedure

Patient:

Note: All result statuses are Final unless otherwise noted.

Tests: (1) Surgical Procedure

Order Note:

COPY TO PHYSICIAN(S):

DATE RECEIVED:

SPECIMEN(S) SUBMITTED:

A. Outside Slide For Review

SPECIAL ANATOMIC STUDIES REQUESTED:

PRE/POST OP DIAGNOSIS:

CLINICAL INFORMATION:

OPERATION PERFORMED: Endocervical biopsy

DATE OF OPERATION: CULTURES TAKEN?

DATE DICTATED: DATE TRANSCRIBED:

GROSS DESCRIPTION: Received from is 1 H and E
stained slide labeled and a surgical pathology report with a
surgical number the patient's name a
identifying the specimen as an endocervical biopsy (mass protruding from
vagina) .

MICROSCOPIC: Microscopic examination is performed.
Surgical Pathology Fellow)

DIAGNOSIS:

[page 3 of 3]
printed:

Page 2
Chart Document

Female DOB:

Year Old

Home:

Office:

MRN:

A. Specimen designated "Endocervical biopsy and Mass protruding from vagina" (outside case number :

1. Invasive squamous cell carcinoma with focal basaloid features.
2. Histological grade G3 (poorly differentiated).
3. Stromal invasion: Extent cannot be assessed.

(Electronically signed) -

My signature is attestation that I have personally reviewed the submitted material(s) and the above diagnosis reflects that evaluation.

! SURG

COMPLETED

Note: An exclamation mark (!) indicates a result that was not dispersed into the flowsheet.

Document Creation Date:

(1) Order result status: Unknown
Collection or observation date-time:
Requested date-time:
Receipt date-time:
Reported date-time:
Referring Physician:
Ordering Physician:
Specimen Source: Outside Slide For Review
Producer ID:
Filler Order Number:
Lab site:

Signed by

Source: NCI Genomic Data Commons file 9ad187bf-99bc-413e-841e-8fa9ed82d752 (TCGA-EK-A2PG.373213AD-4641-426B-AD9F-6C868CAE2868.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).